Somatic mutation profile of tumor specimen TCGA-DU-7300-01A (aliquot TCGA-DU-7300-01A-21D-2086-08) from TCGA case TCGA-DU-7300, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 53.7 years (19,610 days).
Specimen TCGA-DU-7300-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dbdc3f2-9df8-4635-8e93-41f5cb607dc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7300-10A (Blood Derived Normal), aliquot TCGA-DU-7300-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b05e5468-8ea4-436e-a882-0933c3a76aae

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, In Frame Del 10, Frame Shift Del 9, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.829_831del p.E277del | In Frame Del (DEL) | VAF 21/85 reads (25%) | catalogued as rs796051913; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 8/32 reads (25%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3R1 | c.1317_1319del p.E439del (on ENST00000521381 / NM_181523.3; = p.E169del on NM_181504.4) | In Frame Del (DEL) | VAF 10/31 reads (32%) | hotspot (GDC flag); catalogued as rs1131692242; called by pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH1C | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs78836241, COSV72463534; called by muse, mutect2, varscan2
- ALMS1 | c.9616_9618del p.T3206del | In Frame Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs762803723; called by pindel, varscan2
- BTG4 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs140812937; called by muse, mutect2, varscan2
- CDC14B | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV55790046; called by muse, mutect2, varscan2
- DNAJC28 | c.1130T>A p.M377K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58721882; called by muse, mutect2, varscan2
- EID2B | c.362_365del p.F121Wfs*27 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs751435337; called by mutect2, pindel, varscan2
- EPC2 | c.1725_1726del p.G577Yfs*48 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs756428805; called by mutect2, pindel, varscan2
- GALNT13 | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101222728, COSV67242576; called by muse, mutect2, varscan2
- GALNT18 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1375315849, COSV57152428; called by muse, mutect2, varscan2
- GFAP | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs762881584, COSV53651742; called by muse, mutect2, varscan2
- GPR50 | c.1557C>A p.D519E | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV54440547; called by muse, mutect2, varscan2
- HDAC10 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53134019; called by muse, mutect2, varscan2
- HS6ST2 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as COSV63715143; called by mutect2, varscan2
- IPO11 | c.1138_1140del p.E380del | In Frame Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs1277112118; called by pindel, varscan2
- ITGA8 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs561911227, COSV65231516; called by muse, mutect2, varscan2
- KIAA1549 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746094701, COSV54319680; called by muse, mutect2
- LATS2 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV66877189, COSV66877337; called by muse, mutect2, varscan2
- LILRA1 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52182361; called by muse, mutect2, varscan2
- LRP3 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs761624800, COSV53505389; called by muse, mutect2, varscan2
- OTOF | c.5027G>A p.R1676H (on ENST00000272371 / NM_194248.3; = p.R909H on NM_004802.4) | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs143889717; called by muse, mutect2, varscan2
- PKHD1L1 | c.8738C>T p.S2913L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1165204640, COSV65746947; called by muse, mutect2, varscan2
- RPS6KA3 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV65386790, COSV65388464; called by muse, mutect2, varscan2
- SCN2A | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51847305; called by muse, mutect2, varscan2
- SET | c.741_743del p.E247del (on ENST00000372692 / NM_001374326.1; = p.E234del on NM_003011.4) | In Frame Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs768750318; called by pindel, varscan2
- TBCK | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750999870, COSV56753360; called by muse, varscan2
- TCP1 | c.1049_1051del p.E350del | In Frame Del (DEL) | VAF 26/132 reads (20%) | catalogued as rs746657080; called by pindel, varscan2
- TFE3 | c.1527C>A p.H509Q | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV59947912; called by muse, mutect2, varscan2
- TMEM131 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1337714022, COSV51780017; called by muse, mutect2, varscan2
- FUBP1 | c.248_250+1del p.X83_splice | Splice Site (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- IREB2 | c.811_813del p.L271del | In Frame Del (DEL) | VAF 18/66 reads (27%) | called by pindel, varscan2
- MTREX | c.2661_2663del p.L888del | In Frame Del (DEL) | VAF 32/122 reads (26%) | called by mutect2, pindel, varscan2
- NBEA | c.5972_5975del p.R1991Kfs*43 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- PAGE1 | c.108_109del p.Q38Gfs*6 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1388_1389del p.Y463* (on ENST00000521381 / NM_181523.3; = p.Y193* on NM_181504.4) | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by pindel, varscan2
- PRAMEF1 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.041); called by mutect2, varscan2
- PRAMEF14 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- RLF | c.1605_1606del p.D537Qfs*8 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- TRIM28 | c.1982+4_1982+7del p.X661_splice | Splice Site (DEL) | VAF 94/214 reads (44%) | called by mutect2, pindel, varscan2
- TSHZ1 | c.289_291del p.K97del (on ENST00000580243 / NM_001308210.2; = p.K52del on NM_005786.6) | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- TTBK2 | c.2378_2382del p.L793* | Frame Shift Del (DEL) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- ZHX2 | c.1583_1584del p.F528Cfs*14 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3460_3463del p.V1154Ifs*7 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by pindel, varscan2
- AKR1C8P | c.300G>A p.P100= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs782099265; called by muse, mutect2, varscan2
- ANKRD17 | c.1719A>G p.Q573= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as COSV58223509; called by muse, mutect2, varscan2
- CBLIF | c.147A>G p.S49= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV57239567; called by muse, mutect2, varscan2
- CCDC113 | c.234A>G p.R78= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as COSV54686765; called by muse, mutect2, varscan2
- CNTN1 | c.1353G>A p.G451= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1325928974, COSV61641973; called by muse, mutect2, varscan2
- ELANE | c.117C>T p.H39= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV52255820; called by muse, mutect2, varscan2
- IRS4 | c.1173C>T p.D391= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as COSV64534667; called by muse, mutect2, varscan2
- MPHOSPH8 | c.972C>T p.T324= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs745631715, COSV64056303, COSV64056349; called by muse, mutect2, varscan2
- PKD1L1 | c.8061C>T p.P2687= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as rs138774842; called by muse, mutect2, varscan2
- RIF1 | c.3384C>T p.D1128= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1410224653, COSV54619726; called by muse, mutect2, varscan2
- ZNF630 | c.1503T>G p.P501= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV52097311; called by muse, mutect2, varscan2
- MIR520H | n.29A>G | RNA (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
